Gene-level copy-number profile of tumor specimen ALCH-B2OJ-TTP1-A from ALCHEMIST case ALCH-B2OJ, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 66.0 years (24,121 days).
Specimen ALCH-B2OJ-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file fe08fbfa-dce3-431c-b2e6-d23f405f7be3.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B2OJ-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,767 have no estimate.
https://portal.gdc.cancer.gov/files/37d231a4-9f12-4026-9e19-366316ae741f

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 1,202; copy number 1: 24,202; copy number 2: 29,251; copy number 3: 1,491; copy number 4: 1,390; copy number 5: 1,004; copy number 6: 292; copy number 7: 3; copy number 8: 12; copy number 10: 2; copy number 12: 4; copy number 13: 1; copy number 14: 2.

Homozygous deletions (total copy number 0; autosomes only): 690 genes in 207 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:4,175,528–4,792,534, 6 genes: EEF1DP6, LINC01777, Z98747.1, LINC01646, AJAP1, Z98886.1.
- chr1:11,806,096–11,880,406, 7 genes (within-gene range 0–1): CLCN6, AL021155.2, AL021155.3, NPPA, AL021155.1, NPPB, SBF1P2.
- chr1:12,716,110–12,928,253, 14 genes (within-gene range 0–2): AADACL3, C1orf158, PRAMEF12, PRAMEF1, LINC01784, PRAMEF11, PRAMEF30P, HNRNPCL1, PRAMEF2, PRAMEF4, PRAMEF10, PRAMEF7, RNU6-1072P, PRAMEF29P.
- chr1:13,049,476–13,516,270, 26 genes (within-gene range 0–2): PRAMEF27, HNRNPCL3, PRAMEF25, PRAMEF35P, HNRNPCL2, PRAMEF36P, AC245056.1, PRAMEF26, HNRNPCL4, PRAMEF9, PRAMEF13, PRAMEF18, PRAMEF31P, PRAMEF5, PRAMEF32P, RNU6-771P, PRAMEF8, PRAMEF33, PRAMEF15, AC243961.1, PRAMEF14, PRAMEF19, PRAMEF17, PRAMEF20, LRRC38, AL354712.1.
- chr1:17,539,698–18,748,866, 11 genes: ARHGEF10L, LINC02810, ACTL8, LINC01654, IGSF21, AL365209.1, IGSF21-AS1, AL591896.1, KLHDC7A, AL031737.1, PAX7.
- chr1:20,290,919–20,618,903, 9 genes: VWA5B1, AL020998.1, LINC01141, AL139254.1, CAMK2N1, MUL1, RPS4XP4, FAM43B, CDA.
- chr1:22,652,762–22,965,338, 6 genes (within-gene range 0–1): C1QB, EPHB2, MIR4684, AL512444.1, MIR4253, LACTBL1.
- chr1:25,959,767–26,068,436, 7 genes: PAFAH2, RNU6-110P, AL592064.1, AL592064.2, EXTL1, SLC30A2, TRIM63.
- chr1:26,169,516–26,229,840, 6 genes: AL391650.1, ZNF593, CNKSR1, CATSPER4, ZPLD2P, AL355877.2.
- chr1:28,526,318–28,583,132, 9 genes: PRDX3P2, AL513497.1, TRNAU1AP, SNHG12, SNORD99, SNORA61, SNORA44, SNORA16A, SNORA16A.
- chr1:29,329,620–30,037,612, 5 genes: LINC01756, AL671862.1, AC092265.1, AL645944.1, LINC01648.
- chr2:219,434,843–219,516,877, 6 genes (within-gene range 0–1): SPEG, ASIC4-AS1, AC053503.6, SPEGNB, AC053503.4, GMPPA.
- chr2:230,836,909–231,025,055, 9 genes: AC012507.2, ITM2C, GCSIR, GPR55, AC012507.1, AC012507.3, COX20P2, SPATA3-AS1, SPATA3.
- chr3:75,521,803–75,670,185, 14 genes: SNRPCP10, AC133041.1, RPS3AP15, AC108724.1, OR7E121P, UNC93B3, RPL23AP49, AC108724.2, CLUHP10, MIR1324, AGGF1P3, RARRES2P1, FRG2C, DUX4L26.
- chr5:174,045,706–174,730,896, 11 genes (within-gene range 0–1): NSG2, AC113423.1, AC113423.2, AC011333.1, AC025752.1, LINC01411, GAPDHP71, SUMO2P6, AC108112.1, HIGD1AP3, MSX2.
- chr5:176,542,511–176,646,644, 7 genes (within-gene range 0–1): CDHR2, RN7SL684P, Y_RNA, GPRIN1, SNCB, MIR4281, EIF4E1B.
- chr5:178,130,996–178,590,393, 11 genes (within-gene range 0–1): RMND5B, NHP2, AC136632.2, GMCL2, HNRNPAB, PHYKPL, COL23A1, AC136601.2, AC136601.1, RN7SL646P, AC008659.1.
- chr7:63,326,674–63,359,306, 7 genes: AC006455.1, ARAFP3, AC006455.6, AC006455.5, AC006455.2, AC006455.3, AC006455.4.
- chr9:43,109,866–60,964,196, 8 genes: FP325317.1, FP325317.2, BX088702.1, SPATA31A5, AL590491.1, FAM74A6, AL590491.2, AL590491.3.
- chr10:116,620,953–116,850,251, 5 genes (within-gene range 0–1): PNLIPRP2, C10orf82, AC016825.1, HSPA12A, RPL5P27.
- chr10:117,128,521–117,279,430, 8 genes (within-gene range 0–2): VAX1, MIR3663HG, MIR3663, RPL12P26, KCNK18, AL731557.1, SLC18A2, AL391988.1.
- chr10:117,425,194–117,831,244, 6 genes: AC005871.2, EMX2OS, EMX2, AC005871.1, LINC02674, AL513324.1.
- chr10:123,323,422–123,697,399, 5 genes: AL160290.2, LINC02641, AL160290.1, AL357127.1, GPR26.
- chr10:130,213,488–131,311,721, 6 genes: LINC02646, AL157712.1, Y_RNA, MIR378C, TCERG1L, TCERG1L-AS1.
- chr13:111,596,009–112,331,225, 10 genes (within-gene range 0–1): LINC02337, LINC00354, AL138691.1, SOX1-OT, SOX1, AL356961.1, LINC00404, LINC01070, LINC01043, LINC01044.
- chr15:21,990,074–22,095,857, 8 genes (within-gene range 0–7): AC134980.1, OR11H3P, AC134980.2, OR11K1P, OR4Q1P, OR4H6P, OR4M2, OR4N4.
- chr15:23,083,094–23,856,375, 24 genes: ELMO2P1, GOLGA6L1, AC116165.1, GOLGA8DP, RN7SL106P, ABCB10P1, AC116165.2, MIR4509-1, AC116165.3, AC242376.1, HERC2P7, AC100756.2, AC100756.1, GOLGA8S, RN7SL536P, HERC2P6, GOLGA6L2, MIR4508, MKRN3, AC126407.1, MAGEL2, NDN, AC087490.1, RNU6-741P.
- chr15:25,178,738–25,187,616, 6 genes (within-gene range 0–1): SNORD115-5, SNORD115-6, SNORD115-7, SNORD115-8, SNORD115-9, SNORD115-10.
- chr15:25,193,321–25,211,877, 11 genes (within-gene range 0–1): SNORD115-13, SNORD115-14, SNORD115-15, SNORD115-16, SNORD115-17, SNORD115-18, SNORD115-19, SNORD115-20, SNORD115-21, SNORD115-22, SNORD115-23.
- chr15:25,225,203–25,250,940, 15 genes (within-gene range 0–1): SNORD115-30, SNORD115-31, SNORD115-32, SNORD115-33, SNORD115-34, SNORD115-35, SNORD115-36, SNORD115-37, SNORD115-38, SNORD115-39, SNORD115-40, SNORD115-41, SNORD115-42, SNORD115-43, SNORD115-44.
- chr15:29,120,254–29,680,957, 8 genes (within-gene range 0–1): FAM189A1, AC061965.2, AC061965.1, NSMCE3, AC107980.1, AC102941.1, TUBBP8, AC022613.1.
- chr15:32,384,937–32,455,634, 9 genes: DNM1P31, GOLGA8K, RN7SL185P, AC135983.1, ULK4P1, U8, DNM1P32, GOLGA8O, RN7SL539P.
- chr17:12,973,033–13,100,939, 5 genes (within-gene range 0–1): AC005274.1, AC005277.2, AC005277.1, ELAC2, AC005303.1.
- chr19:44,926,804–44,993,341, 6 genes: APOC1P1, APOC4, APOC4-APOC2, APOC2, AC011481.1, CLPTM1.
- chr19:50,621,307–50,771,732, 6 genes: SYT3, C19orf81, SHANK1, CLEC11A, GPR32P1, GPR32.
- chr19:50,797,704–50,837,213, 7 genes (within-gene range 0–1): C19orf48, SNORD88B, SNORD88A, SNORD88C, LINC01869, KLK1, KLK15.
- chr19:53,666,679–53,706,336, 20 genes: MIR512-1, MIR512-2, MIR1323, MIR498, MIR520E, MIR515-1, MIR519E, MIR520F, MIR515-2, MIR519C, MIR1283-1, MIR520A, MIR526B, MIR519B, MIR525, MIR523, MIR518F, MIR520B, MIR518B, MIR526A1.
- chr19:53,721,076–53,824,394, 35 genes: MIR517B, MIR520G, MIR516B2, MIR526A2, MIR518E, MIR518A1, RNU6-980P, MIR518D, MIR516B1, MIR518A2, MIR517C, MIR520H, RNU6-982P, MIR521-1, RNU6-751P, MIR522, MIR519A1, MIR527, MIR516A1, MIR1283-2, RNU6-1041P, MIR516A2, AC011453.1, MIR519A2, RNU6-165P, HMGN1P32, SEPTIN7P8, AC008753.1, AC008753.3, MIR371A, MIR371B, MIR372, MIR373, AC008753.2, NLRP12.
- chr19:54,200,809–54,249,003, 6 genes (within-gene range 0–1): RPS9, AC245052.2, LILRB3, AC245052.7, AC245052.3, LILRA6.
- chr19:56,669,941–57,222,846, 17 genes (within-gene range 0–1): AC006115.2, OR5AH1P, ZIM2, AC006115.1, PEG3, MIMT1, AC004792.1, AC044792.1, RPL7AP69, AC025588.4, USP29, ZIM3, AC025588.2, AC025588.3, DUXA, AC025588.1, ZNF264.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,320 genes in 73 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:39,838,110–40,097,260, 9 genes, copy number 5–6: TRIT1, Y_RNA, MYCL, MYCL-AS1, Y_RNA, MFSD2A, AL663070.1, CAP1, PPT1.
- chr1:45,530,927–46,185,962, 24 genes, copy number 5: HMGB1P48, AKR1A1, AL355480.3, AL355480.1, NASP, AL355480.2, AL355480.4, CCDC17, GPBP1L1, RPS15AP10, AL604028.2, TMEM69, IPP, AL604028.1, AL603882.1, MAST2, TMA16P2, PIK3R3, P3R3URF-PIK3R3, AL358075.1, AL358075.3, AL358075.2, TSPAN1, P3R3URF.
- chr1:52,927,276–53,051,698, 7 genes, copy number 5: SCP2, AC099677.4, AC099677.6, AC099677.5, H3P2, RRAS2P1, TUBBP10.
- chr3:119,780,484–120,094,994, 7 genes, copy number 5 (within-gene range 4–5): NR1I2, PHBP8, GSK3B, AC092910.4, AC078856.1, AC092910.1, AC092910.2.
- chr3:120,512,850–120,783,069, 7 genes, copy number 5: AC126182.2, NDUFB4, HGD, RABL3, MTCO1P29, MTCO2P29, GTF2E1.
- chr3:120,908,072–122,892,416, 38 genes, copy number 5: STXBP5L, AC072026.1, MIR5682, AC078857.1, AC079841.1, AC079841.2, POLQ, RPL7AP11, ARGFX, FBXO40, HCLS1, RN7SL172P, RNU4-62P, GOLGB1, IQCB1, EAF2, SLC15A2, ILDR1, Y_RNA, CD86, CASR, HNRNPA1P23, CSTA, CCDC58, FAM162A, WDR5B, AC083798.2, AC083798.1, KPNA1, AC096861.1, PARP9, DTX3L, PARP15, EIF4BP8, PARP14, HSPBAP1, SLC49A4, LINC02035.
- chr3:124,374,332–125,595,497, 25 genes, copy number 5: MIR6083, RNU6-143P, AC022336.2, UMPS, MIR544B, AC022336.1, ITGB5, ITGB5-AS1, AC022336.3, 7SK, ENO1P3, MUC13, HEG1, RNA5SP137, SLC12A8, RNU6-230P, MIR5092, ZNF148, DUTP1, DNAJB6P7, RNU6-232P, SNX4, Y_RNA, Y_RNA, OSBPL11.
- chr3:127,689,062–128,153,914, 8 genes, copy number 5 (within-gene range 4–5): MGLL, KBTBD12, RNA5SP139, SEC61A1, RUVBL1, RNU2-37P, RUVBL1-AS1, RNU6-823P.
- chr3:129,001,629–129,218,350, 10 genes, copy number 5 (within-gene range 4–5): EFCC1, AC108673.1, GP9, RAB43, ISY1-RAB43, AC108673.2, ISY1, AC108673.3, CNBP, RPS27P12.
- chr3:129,632,019–130,055,920, 13 genes, copy number 5: AC023162.1, TMCC1, RNY3P13, U6, AC083799.1, TMCC1-AS1, AC083906.3, TRH, AC083906.1, AC083906.2, OR7E129P, OR7E21P, AC083906.4.
- chr3:130,560,334–133,037,052, 39 genes, copy number 5: COL6A6, PIK3R4, RN7SKP212, GSTO3P, ATP2C1, AC055733.4, AC055733.2, Y_RNA, AC055733.1, AC055733.3, ASTE1, NEK11, AC116424.1, RNU6-726P, AC010210.1, NUDT16P1, NUDT16, AC107027.3, MRPL3, SNORA58, AC107027.1, BCL2L12P1, CPNE4, AC107027.2, MIR5704, PSMC2P1, RPL7P16, ACP3, AC020633.1, NIP7P2, DNAJC13, ACAD11, NPHP3-ACAD11, ACKR4, HSPA8P19, UBA5, NPHP3, NPHP3-AS1, AC079942.1.
- chr3:133,543,064–133,754,576, 8 genes, copy number 5 (within-gene range 4–5): AC022296.4, AC022296.3, AC022296.1, CDV3, TOPBP1, INHCAP, RNU6-678P, RNA5SP140.
- chr3:135,925,891–136,197,241, 7 genes, copy number 5: AC092989.1, NDUFS6P1, PPP2R3A, AC072039.1, AC072039.2, MSL2, TDGF1P6.
- chr3:136,250,340–137,011,085, 15 genes, copy number 5 (within-gene range 5–7): PCCB, STAG1, RNU6-1284P, HMGN1P10, RNU6-789P, AC117382.1, AC117382.2, AC096992.1, SLC35G2, NCK1-DT, AC096992.2, NCK1, RAD51AP1P1, IL20RB, IL20RB-AS1.
- chr3:138,494,344–138,953,990, 11 genes, copy number 5: CEP70, FAIM, PPIAP72, PIK3CB, GAPDHP39, RPL23AP40, EEF1A1P25, ATP5MC1P3, LINC01391, FOXL2, FOXL2NB.
- chr3:141,324,213–146,606,216, 76 genes, copy number 5–6 (within-gene range 4–7) (broad region; genes not listed).
- chr3:147,844,123–148,696,204, 12 genes, copy number 5: AC092925.1, AC092958.1, AC092958.4, LINC02032, AC092958.3, AC092958.2, AC025566.1, HNRNPA1P20, LINC02045, LINC02046, AC069410.1, RPL38P1.
- chr3:148,850,933–150,763,477, 56 genes, copy number 5–8 (within-gene range 4–8): AC092979.1, CPA3, AC092979.2, UBQLN4P1, GYG1, HLTF, HLTF-AS1, Y_RNA, MED28P2, HPS3, CP, CPHL1P, AC093001.1, TM4SF18, AC073522.1, TM4SF1, TM4SF1-AS1, AC108751.4, AC108751.2, AC108751.3, FKBP1AP4, AC108751.1, TM4SF4, AC108751.5, WWTR1, RNU6-1098P, WWTR1-IT1, WWTR1-AS1, COMMD2, ANKUB1, RNU6-507P, RNF13, RNU6-720P, NPM1P29, PFN2, AC117395.1, TMEM183B, PPIAP73, HNRNPA1P24, AC117386.2, AC022494.1, LINC01998, RPL32P9, AC117386.1, LINC01213, U2, LINC01214, TSC22D2, SERP1, EIF2A, SELENOT, AC069236.1, ERICH6, ERICH6-AS1, SNRPCP3, SIAH2.
- chr3:151,197,832–154,677,119, 53 genes, copy number 5–8 (within-gene range 4–8): GPR171, P2RY14, SETP11, AC078816.1, GPR87, P2RY13, P2RY12, IGSF10, MRPL42P6, AC117454.1, MIR5186, LINC02066, AADACL2, AADACL2-AS1, AC068647.1, AADACP1, AC068647.2, AADAC, SUCNR1, AC108718.1, MBNL1, MBNL1-AS1, TMEM14EP, Y_RNA, AC026347.1, AC092924.1, ATP5MGP5, P2RY1, HMGN2P13, AC117394.1, AC117394.2, RAP2B, RN7SL300P, AC078788.1, AC078788.2, LINC02006, LINC02877, RNU6-901P, Y_RNA, AC068985.1, U8, RPL21P42, ARHGEF26-AS1, ARHGEF26, DHX36, AC134026.1, AC134026.2, GPR149, DDX50P2, AC092994.1, SYPL1P1, DYNLL1P5, RPL9P15.
- chr3:155,024,124–155,761,217, 16 genes, copy number 5: MME, MME-AS1, LINC01487, STRIT1, AC104831.1, PABPC1P10, PLCH1, AC108729.3, AC108729.2, AC108729.1, RN7SL715P, PLCH1-AS1, PLCH1-AS2, RPL6P7, AC104472.1, AC104472.2.
- chr3:156,539,553–157,174,040, 18 genes, copy number 5: SSR3, TIPARP-AS1, TIPARP, METTL15P1, LINC00886, PA2G4P4, LEKR1, KLF3P2, AC117392.1, RN7SKP177, LINC00880, LINC02029, LINC00881, CCNL1, Y_RNA, KRT18P34, AC104411.1, RNA5SP146.
- chr3:157,814,822–160,225,299, 36 genes, copy number 5: AC079943.2, RN7SKP46, AC079943.1, SHOX2, RSRC1, AC074276.1, AC074276.2, AC106707.2, AC106707.1, MLF1, MTAPP1, AC025033.1, GFM1, LXN, AC080013.3, RARRES1, MFSD1, AC080013.1, RPL35AP9, AC080013.2, AC080013.4, GPR79, AC092999.1, IQCJ-SCHIP1, IQCJ, MIR3919, AC063955.1, AC092943.2, AC092943.1, IQCJ-SCHIP1-AS1, RNU2-31P, SCHIP1, IL12A-AS1, IL12A, LINC01100, BRD7P2.
- chr3:160,227,454–161,503,942, 27 genes, copy number 5 (within-gene range 4–5): AC079594.1, IFT80, RPL35AP10, SMC4, MIR15B, MIR16-2, TRIM59, B3GAT3P1, RNU7-136P, KPNA4, SCARNA7, KRT8P12, RPL6P8, ARL14, SNORA72, AC069224.1, PPM1L, B3GALNT1, NMD3, AC108738.1, EEF1GP4, PSMC1P7, SPTSSB, LINC02067, AC112491.1, RPL23AP42, OTOL1.
- chr3:164,978,898–167,479,004, 24 genes, copy number 5 (within-gene range 4–5): SI, Y_RNA, LINC02023, SLITRK3, LINC01322, BCHE, MTND4P17, MTND4LP10, MTND3P7, MTCO3P38, MCUR1P2, AC104629.1, LINC01326, AC072046.2, RN7SKP298, PSAT1P4, AC072046.1, CBX1P5, AC069439.2, AC069439.1, PPIAP74, ZBBX, LINC01327, SERPINI2.
- chr3:167,683,298–169,663,775, 25 genes, copy number 5–6: PDCD10, HMGN1P8, SERPINI1, AC079822.1, LRRC77P, AC026353.1, MEMO1P3, AC128713.1, HMGN2P26, GOLIM4, AC069243.1, EGFEM1P, AC124893.1, RNU2-20P, MIR551B, RPSAP33, RPL21P43, LINC02082, AC092954.1, AC092954.2, LINC01997, MECOM, MECOM-AS1, RPL22P1, AC007849.1.
- chr3:169,764,520–170,860,993, 32 genes, copy number 5–6 (within-gene range 4–6): TERC, Telomerase-vert, ACTRT3, AC078802.1, MYNN, AC078795.1, LRRC34, AC078795.3, AC078795.2, LRRIQ4, LRRC31, KRT18P43, SAMD7, AC008040.2, AC008040.1, AC008040.3, SEC62, SEC62-AS1, GPR160, RNU4-38P, KMT5AP3, PHC3, RNU6-315P, PRKCI, Y_RNA, AC073288.1, SKIL, AC073288.2, CLDN11, AC026316.4, MIR6828, SLC7A14-AS1.
- chr3:170,691,997–173,141,235, 40 genes, copy number 5–6: AC026316.5, AC026316.2, RPL22L1, EIF5A2, AC061708.1, KLF7P1, RNU1-70P, SLC2A2, TNIK, MIR569, Y_RNA, AC092919.1, AC092919.2, RNU6-348P, AC008134.1, PLD1, TMEM212-AS1, TMEM212, TMEM212-IT1, AC055714.1, FNDC3B, RPS27AP8, RN7SL141P, AC092964.1, BZW1P1, GHSR, TNFSF10, AC007919.1, LINC02068, SLC31A1P1, NCEH1, AC007919.2, RNU6-547P, AC108667.2, ECT2, SNORA72, RNU4-4P, ATP5MC1P4, AC108667.1, SPATA16.
- chr3:173,396,284–180,037,053, 80 genes, copy number 5–6 (broad region; genes not listed).
- chr3:180,868,141–182,985,953, 36 genes, copy number 5–6 (within-gene range 4–6): FXR1, AC108734.1, DNAJC19, SOX2-OT, AC083904.1, RNU6-4P, FAUP2, AC068308.1, RPL7AP25, AC125613.1, AC125613.2, AC117415.1, SOX2, AC117415.2, RN7SL703P, RNA5SP150, AC007547.2, AC007547.1, LINC01206, RN7SKP265, AC012081.1, AC084211.1, LINC01994, EIF4EP3, LINC01995, AC021055.1, RPL7L1P8, LINC02031, AC083801.1, AC083801.2, AC069431.1, ATP11B, AC069431.2, AC092953.2, DCUN1D1, AC092953.1.
- chr3:183,178,043–184,508,399, 56 genes, copy number 5: MCF2L2, B3GNT5, RNA5SP151, LINC00888, SNORA63D, AC092960.2, SNORA63E, AC092960.1, AC092960.3, KLHL6, KLHL6-AS1, AC068769.1, KLHL24, YEATS2, YEATS2-AS1, AC131160.1, MAP6D1, PARL, RPSAP31, MIR4448, CYP2AB1P, ABCC5, ABCC5-AS1, EEF1A1P8, HTR3D, HTR3C, HTR3C2P, Y_RNA, HTR3E-AS1, HTR3E, HSP90AA5P, AC131235.3, AC131235.2, EIF2B5, AC131235.1, DVL3, AP2M1, ABCF3, VWA5B2, MIR1224, ALG3, EEF1AKMT4, EEF1AKMT4-ECE2, CAMK2N2, ECE2, PSMD2, EIF4G1, SNORD66, FAM131A, CLCN2, POLR2H, THPO, CHRD, LINC02054, AC128714.2, LINC01839.
- chr3:184,812,143–185,825,042, 15 genes, copy number 5: VPS8, C3orf70, EHHADH-AS1, EHHADH, EIF2S2P2, MIR5588, MAP3K13, RPL4P4, TMEM41A, LIPH, SENP2, AC133473.1, IGF2BP2, IGF2BP2-AS1, MIR548AQ.
- chr3:186,538,441–191,398,659, 85 genes, copy number 5–8 (broad region; genes not listed).
- chr3:191,952,349–194,145,971, 34 genes, copy number 5: AC026320.2, AC026320.1, AC026320.3, RN7SKP222, FGF12, FGF12-AS1, FGF12-AS2, FGF12-AS3, AC026671.1, RNU1-20P, MB21D2, AC092966.1, VEZF1P1, PLAAT1, ATP13A5, ATP13A5-AS1, ATP13A4, ATP13A4-AS1, AC048351.1, OPA1, OPA1-AS1, Y_RNA, RN7SL447P, AC069421.1, LINC02038, LINC02026, AC024559.1, DPPA2P3, LINC02028, AC024559.2, AC080129.1, AC080129.2, HES1, RN7SL215P.
- chr3:195,274,745–195,561,580, 10 genes, copy number 5–6: ACAP2, ACAP2-IT1, AC090018.1, Y_RNA, PPP1R2, RNU6ATAC24P, AC069213.1, RN7SL73P, AC069213.3, AC069213.2.
- chr3:195,836,193–196,969,060, 56 genes, copy number 5–6: LINC01983, KIF3AP1, TNK2, MIR6829, AC124944.3, TNK2-AS1, AC124944.2, RNU2-11P, AC124944.1, SDHAP1, AC024937.3, AC024937.2, TFRC, AC024937.1, RNU7-18P, LINC00885, ZDHHC19, Y_RNA, SLC51A, PCYT1A, AC069257.3, AC069257.1, TCTEX1D2, AC069257.2, TM4SF19-TCTEX1D2, TM4SF19-AS1, TM4SF19, RNU6-910P, UBXN7, RNU6-1279P, RN7SL434P, RN7SL738P, AC083822.1, UBXN7-AS1, AC117490.1, RNF168, AC117490.2, SMCO1, AC092933.1, RPS29P3, WDR53, FBXO45, LINC01063, NRROS, PIGX, CEP19, RNU6-646P, PAK2, RNU4-89P, RNU6-42P, SENP5, AC016949.1, NCBP2, NCBP2-AS1, NCBP2AS2, PIGZ.
- chr3:197,634,315–198,123,232, 23 genes, copy number 5: AC024560.2, AC024560.3, AC024560.1, AC024560.5, RUBCN, MIR922, FYTTD1, AC055764.2, LRCH3, AC055764.1, AC144530.1, IQCG, RNU6-858P, RPL35A, LMLN, RNU6-621P, AC135893.1, LMLN-AS1, ANKRD18DP, RNU6-821P, FRG2FP, TUBB8P8, AC073135.1.
- chr8:100,257,060–107,498,055, 132 genes, copy number 6 (within-gene range 1–6) (broad region; genes not listed).
- chr8:133,644,598–138,083,657, 40 genes, copy number 5–6: AC090821.1, Metazoa_SRP, MTND2P7, MTCO1P49, AC133634.1, AC090821.2, AC090821.3, AC110741.1, AC110741.3, AC110741.2, AC105180.2, AC105180.1, ZFAT, AC015599.1, ZFAT-AS1, AC015599.2, AC015599.3, AC087045.1, AC087045.2, AC087045.3, AC083843.3, AC083843.2, MIR30B, MIR30D, AC083843.1, NCRNA00250, AC103764.1, RPL23AP56, LINC01591, AC040914.1, KHDRBS3, MAPRE1P1, RNU1-35P, LINC02055, RNU6-144P, ZYXP1, AC110053.1, AC046195.1, AC046195.2, AC079015.1.
- chr9:30,670,964–31,645,160, 13 genes, copy number 5–14: CDRT15P5, RBMXP2, KRT18P66, KRT18P36, RPS26P2, FTLP4, HSPA8P17, AL354854.1, SLC25A6P2, LINC01243, MTATP6P30, MTCO3P30, HMGB3P23.
- chr20:22,885,670–23,444,930, 20 genes, copy number 5–6: CYB5AP4, AL353132.1, AL049651.1, AL049651.2, SSTR4, THBD, AL118508.3, CD93, LINC00656, AL118508.2, RNA5SP478, AL118508.1, AL390037.1, NXT1-AS1, NXT1, LINC01431, GZF1, NAPB, RNA5SP479, CSTL1.

Autosomal genes at a single copy (total copy number 1): 21,858. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
